Somatic mutation profile of tumor specimen ALCH-ABUA-TTP1-A (aliquot ALCH-ABUA-TTP1-A-1-0-D-A489-36) from ALCHEMIST case ALCH-ABUA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 78.2 years (28,550 days).
Specimen ALCH-ABUA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b86a4626-5b02-4fd2-950c-5af13ac87997.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABUA-NB1-A (Blood Derived Normal), aliquot ALCH-ABUA-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c047ef4a-6005-4c0c-888e-30ad799b16a1

The open-access MAF lists 64 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 19, In Frame Del 3, Splice Site 3, Nonsense Mutation 3, RNA 2, Frame Shift Ins 1, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NTHL1 | c.140-1G>A p.X47_splice (on ENST00000219066; = p.X39_splice on NM_002528.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as rs1411394625; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP2B2 | c.2212C>T p.H738Y (on ENST00000352432; = p.H704Y on NM_001683.5) | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as rs1559545069; called by muse, mutect2, varscan2
- ATP7A | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 38/560 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs782183016, COSV58442083; called by muse, mutect2
- CFH | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 131/678 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs201360629, CM124965, COSV66410451; called by muse, mutect2, varscan2
- EGFR | c.2237_2253delinsTTAAT p.E746_T751delinsVN | In Frame Del (DEL) | VAF 71/681 reads (10%) | catalogued as COSV51770103, COSV51771891, COSV51826919; called by pindel, varscan2*
- EPHB4 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs752453773; called by muse, mutect2, varscan2
- GFRA4 | c.601G>A p.V201I (on ENST00000319242 / NM_145762.3; = p.V171I on NM_022139.4) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs1256491017, COSV51774611; called by muse, mutect2, varscan2
- GNE | c.1732G>A p.G578S (on ENST00000396594 / NM_001128227.3; = p.G547S on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/620 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs1306768272; ClinVar: uncertain significance; called by muse, mutect2
- GRIP2 | c.2707G>A p.A903T (on ENST00000619221; = p.A806T on NM_001080423.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1206893830; called by muse, varscan2
- IGF1R | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.203); catalogued as rs61740868, COSV51294474; called by muse, mutect2, varscan2
- KRT27 | c.817A>T p.R273W | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56971546; called by muse, mutect2, varscan2
- MTMR8 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 50/698 reads (7%) | catalogued as rs1377140596; called by muse, mutect2
- NDUFS5 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs541997196, COSV100880436; called by muse, mutect2, varscan2
- NDUFS6 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.073); catalogued as COSV99059843; called by muse, mutect2, varscan2
- PIP5K1A | c.1318C>T p.R440W (on ENST00000368888 / NM_001135638.2; = p.R427W on NM_003557.3) | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327470594, COSV62960154; called by muse, mutect2, varscan2
- POU3F3 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 37/451 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.203); catalogued as COSV63722546; called by muse, mutect2
- PTEN | c.492+1G>C p.X164_splice | Splice Site (SNP) | VAF 72/383 reads (19%) | catalogued as CD020869, COSV64293587, COSV64301805, COSV64306784; called by muse, mutect2, varscan2
- PYHIN1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs770477176; called by muse, varscan2
- RBPJL | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1221822612; called by muse, mutect2
- RXFP3 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.683); catalogued as rs759379460, COSV57508645; called by muse, mutect2, varscan2
- TERT | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 49/353 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1388678536, COSV57242106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTI1 | c.1353G>A p.W451* | Nonsense Mutation (SNP) | VAF 30/556 reads (5%) | catalogued as COSV65061568; called by muse, mutect2
- ZFP69B | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.315); catalogued as COSV64315052; called by muse, mutect2
- ZFP69B | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs754072556, COSV64315926; called by muse, varscan2
- ADD3 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 24/277 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- DNAH2 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- HS3ST2 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA2 | c.2444C>G p.S815C | Missense Mutation (SNP) | VAF 29/438 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- NEDD1 | c.1879-1G>T p.X627_splice | Splice Site (SNP) | VAF 30/292 reads (10%) | called by mutect2, varscan2
- OCSTAMP | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2
- RAB33A | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 70/455 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM10 | c.2288_2299del p.L763_R766del | In Frame Del (DEL) | VAF 47/359 reads (13%) | called by mutect2, pindel, varscan2
- SEMA3E | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, varscan2
- SLC25A23 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, varscan2
- SNX27 | c.221dup p.Y75Vfs*36 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by mutect2, pindel
- SPINT1 | c.1115-6C>G | Splice Region (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- TTC13 | c.2099G>C p.G700A | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TTN | c.30260C>T p.S10087L (on ENST00000591111; = p.S9160L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/312 reads (7%) | PolyPhen benign (0); called by muse, mutect2
- UBA1 | c.2740C>T p.Q914* | Nonsense Mutation (SNP) | VAF 56/255 reads (22%) | called by muse, mutect2, varscan2
- ZFP69B | c.1374G>C p.Q458H | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- ZSWIM5 | c.3211_3222del p.A1071_L1074del | In Frame Del (DEL) | VAF 41/187 reads (22%) | called by mutect2, pindel, varscan2
- AC092718.8 | c.12A>G p.R4= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ADRA2B | c.1134C>T p.G378= | Silent (SNP) | VAF 92/552 reads (17%) | catalogued as rs746886753, COSV69787350; called by muse, mutect2, varscan2
- ATP7A | c.2967C>T p.F989= | Silent (SNP) | VAF 56/436 reads (13%) | called by muse, mutect2, varscan2
- CACNA1C | c.6462C>T p.S2154= (on ENST00000399634 / NM_001167625.1; = p.S2083= on NM_000719.7) | Silent (SNP) | VAF 27/281 reads (10%) | catalogued as rs1312632905; called by muse, mutect2, varscan2
- CNTNAP5 | c.2757G>A p.T919= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs993689069, COSV70475303; called by muse, varscan2
- FRZB | c.468G>A p.A156= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- HID1 | c.369C>T p.P123= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs765467682; called by muse, mutect2, varscan2
- IQCH | c.195A>G p.L65= | Silent (SNP) | VAF 22/261 reads (8%) | called by muse, mutect2
- LRMDA | c.483G>A p.L161= | Silent (SNP) | VAF 90/433 reads (21%) | called by muse, mutect2, varscan2
- MARCHF10 | c.2124G>T p.V708= | Silent (SNP) | VAF 13/253 reads (5%) | catalogued as rs1364870058, COSV60885342; called by muse, mutect2
- MROH1 | c.2244G>A p.A748= | Silent (SNP) | VAF 130/696 reads (19%) | called by muse, mutect2, varscan2
- NOM1 | c.513G>A p.R171= | Silent (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2
- NPR3 | c.1338G>A p.P446= | Silent (SNP) | VAF 32/307 reads (10%) | catalogued as rs1459179981, COSV99421947; called by muse, mutect2, varscan2
- OR6B1 | c.198G>C p.L66= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- RNF185 | c.519C>T p.F173= | Silent (SNP) | VAF 33/496 reads (7%) | called by muse, mutect2
- SLC27A2 | c.627A>G p.S209= | Silent (SNP) | VAF 44/478 reads (9%) | called by muse, mutect2
- USP6NL | c.2292C>T p.Y764= | Silent (SNP) | VAF 47/178 reads (26%) | called by muse, mutect2, varscan2
- VSTM5 | c.426C>G p.L142= | Silent (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- ZNF608 | c.555G>C p.G185= | Silent (SNP) | VAF 43/215 reads (20%) | called by muse, mutect2, varscan2
- MIR548I2 | n.67A>T | RNA (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- NPNT | c.*2208G>A | 3'UTR (SNP) | VAF 28/382 reads (7%) | called by muse, mutect2
- TTC41P | n.2793A>G | RNA (SNP) | VAF 66/337 reads (20%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1239G>A | Intron (SNP) | VAF 15/262 reads (6%) | catalogued as rs1225106995; called by muse, mutect2
